Somatic mutation profile of tumor specimen TCGA-92-8065-01A (aliquot TCGA-92-8065-01A-11D-2244-08) from TCGA case TCGA-92-8065, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.1 years (27,049 days).
Specimen TCGA-92-8065-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7721837-5b88-48d3-8642-eb4c8eabcc44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-8065-10A (Blood Derived Normal), aliquot TCGA-92-8065-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef05797d-30c8-430f-904d-8cd40bc6f3d2

The open-access MAF lists 287 somatic variants for this specimen: 200 protein-altering or splice-affecting, 84 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 84, Nonsense Mutation 22, Splice Site 2, Intron 2, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58147482; called by muse, mutect2, varscan2
- ADAMTS18 | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV51411009, COSV99273813; called by muse, mutect2, varscan2
- AFF2 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1246289503, COSV99665699; called by muse, mutect2, varscan2
- AHNAK | c.4897G>C p.E1633Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV57226079, COSV99948987; called by muse, mutect2, varscan2
- AKAP1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV100028204; called by muse, mutect2, varscan2
- ALG5 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1295279808, COSV53507327, COSV99523788; called by muse, mutect2, varscan2
- ALPK2 | c.4917A>C p.E1639D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100864722, COSV64490123; called by muse, mutect2, varscan2
- ALPP | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101235179; called by muse, varscan2
- AP5M1 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99841313; called by muse, mutect2, varscan2
- ARAP3 | c.1757C>T p.T586I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV99500154; called by muse, mutect2, varscan2
- ARC | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100751763; called by muse, mutect2, varscan2
- ARHGAP20 | c.243C>G p.C81W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV52819356, COSV99504997; called by muse, mutect2, varscan2
- ARHGAP32 | c.1099G>C p.E367Q (on ENST00000310343 / NM_001378025.1; = p.E18Q on NM_014715.4) | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV59850139; called by muse, mutect2, varscan2
- ARID1B | c.5185G>C p.E1729Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.182); catalogued as COSV99271190; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs1347912113, COSV100771982; called by muse, mutect2, varscan2
- ATG13 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV100365941; called by muse, mutect2, varscan2
- ATP5F1B | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.09); catalogued as rs1337448142, COSV100008201; called by muse, mutect2, varscan2
- BACH1 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99728586; called by muse, mutect2, varscan2
- BDP1 | c.5776G>C p.E1926Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100703417; called by muse, mutect2, varscan2
- BNIP2 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99985856; called by muse, mutect2, varscan2
- BTK | c.182T>A p.I61N | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as CM016080, CM962536, COSV100437831; called by muse, mutect2, varscan2
- C3 | c.1968G>C p.Q656H | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs1226051289, COSV55580923, COSV99837116; called by muse, mutect2, varscan2
- CACNA1A | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100803040; called by muse, mutect2, varscan2
- CALR | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV100330986; called by muse, mutect2
- CARD14 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100712606; called by muse, mutect2, varscan2
- CCDC171 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52650764, COSV99901649; called by muse, mutect2, varscan2
- CDH11 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51765470; called by muse, mutect2, varscan2
- CEP162 | c.2963G>A p.R988H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371935197; called by muse, mutect2, varscan2
- CERT1 | c.1861C>G p.Q621E (on ENST00000405807 / NM_001130105.1; = p.Q493E on NM_005713.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99783150; called by muse, mutect2, varscan2
- CFAP70 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1465912201, COSV60287608; called by muse, mutect2, varscan2
- CHD6 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100498579; called by muse, mutect2, varscan2
- CLCN2 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99658912; called by muse, mutect2, varscan2
- CLCN5 | c.1737G>C p.K579N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100260349; called by muse, mutect2, varscan2
- CLDN16 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 67/556 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99290329; called by muse, mutect2, varscan2
- CNNM2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.194); catalogued as COSV100881739, COSV100881746; called by muse, mutect2, varscan2
- COL9A1 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV100611767; called by muse, mutect2, varscan2
- CROCC | c.5314G>A p.A1772T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV100977645; called by muse, mutect2, varscan2
- DGKZ | c.3262G>T p.E1088* (on ENST00000454345 / NM_001105540.2; = p.E900* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100551865; called by muse, mutect2, varscan2
- DHX36 | c.2809C>T p.Q937* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100273861; called by muse, mutect2
- DNAJC9 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99654897; called by muse, mutect2, varscan2
- DOCK8 | c.2899C>T p.Q967* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs1563998886, CM1313334, COSV101210036; called by muse, mutect2, varscan2
- DRAP1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100437158; called by muse, mutect2
- DVL3 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV100493757; called by muse, mutect2, varscan2
- ECHDC2 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV64302175; called by muse, mutect2, varscan2
- EED | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV99646552; called by muse, mutect2, varscan2
- EHBP1L1 | c.3120C>G p.S1040R | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100499973; called by muse, mutect2, varscan2
- EPG5 | c.5657C>G p.S1886* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99957877; called by muse, mutect2, varscan2
- FAM120C | c.2084A>T p.E695V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100070381; called by muse, mutect2, varscan2
- FAM120C | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV100069864, COSV100070385; called by muse, mutect2, varscan2
- FAM221A | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as COSV100794366; called by muse, mutect2, varscan2
- FAT2 | c.6157C>T p.Q2053* | Nonsense Mutation (SNP) | VAF 24/127 reads (19%) | catalogued as COSV99943850; called by muse, mutect2, varscan2
- FAT2 | c.5870C>G p.S1957C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV99941557, COSV99943851; called by muse, mutect2, varscan2
- FAT2 | c.4003G>C p.E1335Q | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs753967403, COSV99943853; called by muse, mutect2, varscan2
- FAXC | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV101067218; called by muse, mutect2, varscan2
- FBXW4 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs746538131, COSV100489571; called by muse, mutect2, varscan2
- FCN2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52476889; called by muse, mutect2, varscan2
- FCRL3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100943474; called by muse, mutect2, varscan2
- FUT5 | c.672G>C p.Q224H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); catalogued as COSV99398942; called by muse, mutect2, varscan2
- GABRG2 | c.842C>T p.S281L (on ENST00000361925 / NM_001375343.1; = p.S241L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100729796; called by muse, mutect2, varscan2
- GALNT9 | c.1294G>C p.E432Q (on ENST00000328957 / NM_001122636.2; = p.E66Q on NM_021808.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV100202001; called by muse, mutect2
- GATAD2A | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs371061090; called by muse, mutect2, varscan2
- GPR158 | c.3289G>C p.E1097Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100892548, COSV100894154; called by muse, mutect2, varscan2
- GRIP1 | c.3162G>A p.V1054= (on ENST00000359742 / NM_001379345.1; = p.V1002= on NM_021150.4 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99670561; called by muse, mutect2, varscan2
- H3C7 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99769219; called by muse, mutect2, varscan2
- HAP1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as rs782589621, COSV100169658; called by muse, mutect2, varscan2
- HIF1AN | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as COSV100142827; called by muse, mutect2, varscan2
- HMCN1 | c.15851G>T p.R5284I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV54908867; called by muse, mutect2, varscan2
- HOXA3 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV100415631; called by muse, mutect2, varscan2
- IL36B | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.112); catalogued as COSV99383022; called by muse, mutect2, varscan2
- IL6ST | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV100410992; called by muse, mutect2, varscan2
- IQGAP1 | c.3586A>G p.M1196V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV99185288; called by mutect2, varscan2
- ITPRID1 | c.1019C>G p.S340* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100087241, COSV60072369; called by muse, mutect2, varscan2
- KCNIP2 | c.235G>A p.D79N (on ENST00000356640 / NM_173191.3; = p.D94N on NM_014591.5) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53306712; called by muse, varscan2
- KDR | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55774920; called by muse, mutect2, varscan2
- KIAA1522 | c.2240C>T p.S747L (on ENST00000373480 / NM_001198972.2; = p.S806L on NM_020888.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1357179999, COSV99614976; called by muse, mutect2, varscan2
- KIAA1549L | c.1844G>A p.R615K (on ENST00000321505; = p.R912K on NM_012194.3) | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99684192; called by muse, mutect2, varscan2
- KIF27 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99927224; called by muse, mutect2, varscan2
- KIF4B | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV101469212, COSV101469373; called by muse, mutect2, varscan2
- KMT2C | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as COSV100075354; called by muse, mutect2, varscan2
- KMT2D | c.8804C>G p.S2935* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV56412141; called by muse, mutect2, varscan2
- KPNA1 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724329, COSV60272121; called by muse, mutect2, varscan2
- KRT1 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV99358948; called by muse, mutect2, varscan2
- LCA5L | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV99903824; called by muse, mutect2, varscan2
- LEPR | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs757065349, COSV100756723, COSV60752349; called by muse, mutect2, varscan2
- LGI3 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100103244; called by muse, mutect2, varscan2
- LIMS2 | c.169G>A p.E57K (on ENST00000355119 / NM_001161403.3; = p.E81K on NM_017980.4) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV99760723; called by muse, mutect2, varscan2
- LPIN1 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99878051; called by muse, mutect2, varscan2
- LPIN1 | c.938A>G p.E313G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as COSV99878054; called by muse, mutect2, varscan2
- LTBP3 | c.3538C>T p.R1180C (on ENST00000301873 / NM_001130144.3; = p.R1133C on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99534487; called by muse, mutect2
- LTBP3 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs1565096309, COSV100100182; called by muse, mutect2, varscan2
- MAGEB4 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.951); catalogued as COSV100975069; called by muse, mutect2, varscan2
- MAGED1 | c.1498G>C p.D500H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100431558, COSV100431765; called by muse, mutect2, varscan2
- MAGT1 | c.206C>T p.P69L (on ENST00000618282 / NM_001367916.1; = p.P101L on NM_032121.5) | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781839181, COSV63781108; called by muse, mutect2, varscan2
- MARCKS | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.198); catalogued as rs1237011805, COSV64043111; called by muse, mutect2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MC3R | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368205448, CM110371, COSV99710799; called by muse, mutect2, varscan2
- MICAL2 | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV99818137; called by muse, mutect2, varscan2
- MKI67 | c.7850C>T p.S2617L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); catalogued as COSV64075794; called by muse, varscan2
- MMEL1 | c.1929C>G p.H643Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV56526427, COSV99984315; called by muse, mutect2, varscan2
- MORC1 | c.1176-1G>A p.X392_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99227348; called by muse, mutect2, varscan2
- MRPL15 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99477617; called by muse, mutect2, varscan2
- MYBL1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV101576592; called by muse, mutect2, varscan2
- NPAS4 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 27/135 reads (20%) | catalogued as COSV100215182; called by muse, mutect2, varscan2
- NPAT | c.3131C>A p.T1044K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.711); catalogued as COSV99586262; called by muse, mutect2, varscan2
- NUP85 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.863); catalogued as COSV99822277; called by muse, mutect2, varscan2
- OR14C36 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as COSV100507587, COSV100507619; called by muse, mutect2
- OR1C1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as rs867751906, COSV101376264; called by muse, mutect2
- OR4S1 | c.16A>T p.N6Y | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100180317; called by muse, mutect2, varscan2
- OR5B17 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as COSV62160267; called by muse, mutect2, varscan2
- OSBPL3 | c.268-1G>C p.X90_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100514438; called by muse, mutect2, varscan2
- P2RX2 | c.1419G>C p.Q473H (on ENST00000343948 / NM_170683.4; = p.Q375H on NM_012226.5) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100267855; called by muse, mutect2, varscan2
- PA2G4 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV100306594; called by muse, mutect2, varscan2
- PCDHGA11 | c.1803G>C p.Q601H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); catalogued as COSV99544426; called by muse, mutect2, varscan2
- PCDHGA7 | c.414A>G p.I138M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as COSV99544424; called by muse, mutect2, varscan2
- PCLO | c.10595G>T p.G3532V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61652531; called by muse, mutect2, varscan2
- PCNT | c.7115C>G p.S2372C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV100855577, COSV100855921, COSV64031768; called by muse, mutect2, varscan2
- PLCB1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100571836; called by muse, mutect2, varscan2
- PLEKHN1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV100379249; called by muse, mutect2, varscan2
- POLR1A | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99808238; called by muse, mutect2, varscan2
- PORCN | c.736G>A p.E246K (on ENST00000326194 / NM_203475.3; = p.E235K on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV58225405; called by muse, mutect2, varscan2
- POU3F4 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV100937310; called by muse, mutect2, varscan2
- POU3F4 | c.661A>T p.T221S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV100937311; called by muse, mutect2, varscan2
- PRDM2 | c.4346C>T p.A1449V | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV99342505; called by muse, mutect2, varscan2
- PRKN | c.1367T>G p.V456G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100630650; called by muse, mutect2, varscan2
- PRR19 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV100004048; called by muse, mutect2, varscan2
- PSIP1 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV101050989; called by muse, mutect2, varscan2
- PSMD2 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100031961; called by muse, mutect2, varscan2
- PXN | c.1747C>G p.Q583E (on ENST00000228307 / NM_001080855.3; = p.Q549E on NM_002859.4) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99936183; called by muse, mutect2
- PYGO2 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100868978; called by muse, mutect2, varscan2
- RAPGEF2 | c.3814C>A p.L1272I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.744); catalogued as COSV100031523; called by muse, mutect2, varscan2
- RAPGEF3 | c.2133C>G p.F711L (on ENST00000389212; = p.F669L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99406719; called by muse, mutect2, varscan2
- RFX1 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as rs1184852674, COSV99586375; called by muse, mutect2, varscan2
- RNASEH2B | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as COSV100352397; called by muse, mutect2, varscan2
- RPL23A | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.036); catalogued as COSV99411859; called by muse, mutect2, varscan2
- RUSF1 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs745561054, COSV100393359; called by muse, mutect2
- SAE1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99538140; called by muse, mutect2, varscan2
- SALL2 | c.1324G>C p.D442H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100444554, COSV58103179; called by muse, mutect2, varscan2
- SKA2 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.835); catalogued as COSV100350209, COSV57521423; called by muse, mutect2, varscan2
- SLC1A6 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99694103; called by muse, mutect2, varscan2
- SLC39A4 | c.1924G>T p.E642* (on ENST00000301305 / NM_001374839.1; = p.E617* on NM_017767.3) | Nonsense Mutation (SNP) | VAF 29/213 reads (14%) | catalogued as COSV99433626; called by muse, mutect2, varscan2
- SLCO4C1 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100195616, COSV60518773; called by muse, mutect2, varscan2
- SLITRK3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV99579861; called by muse, mutect2, varscan2
- SMAP1 | c.800C>G p.S267C (on ENST00000370455 / NM_001044305.3; = p.S240C on NM_021940.5) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100017325; called by muse, mutect2, varscan2
- SMG6 | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV99558587; called by muse, mutect2
- SNAPIN | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV62628246; called by muse, mutect2, varscan2
- SNCAIP | c.640A>C p.K214Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV99749858; called by muse, mutect2, varscan2
- SPO11 | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs766700031, COSV100625781; called by muse, mutect2, varscan2
- SPOCK2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100436458; called by muse, mutect2
- SRA1 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV99784137; called by muse, varscan2
- SRA1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51857904, COSV99784138; called by muse, varscan2
- ST8SIA3 | c.987C>A p.N329K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | PolyPhen possibly damaging (0.6); catalogued as COSV100129643, COSV60654621; called by muse, mutect2, varscan2
- STIL | c.1748G>T p.R583I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs759738854, COSV99681238; called by muse, mutect2, varscan2
- STIP1 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100534951; called by muse, mutect2, varscan2
- SULF1 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV52672385, COSV99484002; called by muse, mutect2, varscan2
- SUPT6H | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100112695; called by muse, mutect2, varscan2
- SYCP2 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV100698404; called by muse, mutect2, varscan2
- SYNE1 | c.22594G>T p.E7532* (on ENST00000367255 / NM_182961.4; = p.E7461* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV55020484, COSV55051805; called by muse, mutect2, varscan2
- SYNJ2 | c.4222C>G p.L1408V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.098); catalogued as COSV100840580; called by muse, mutect2, varscan2
- SYTL4 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as rs1177165020, COSV99343241; called by muse, mutect2, varscan2
- TAS2R1 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV101225842; called by muse, mutect2, varscan2
- TASOR2 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100050867; called by muse, mutect2, varscan2
- TBX6 | c.333G>C p.M111I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99661762; called by muse, mutect2, varscan2
- TCEA2 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58659139; called by muse, mutect2
- TENM1 | c.4081C>G p.Q1361E | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100950589; called by muse, mutect2, varscan2
- TET3 | c.4195G>C p.E1399Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101328048; called by mutect2, varscan2
- TIMD4 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99192833; called by muse, mutect2, varscan2
- TM2D1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1345440033, COSV99623969; called by muse, mutect2, varscan2
- TPR | c.5563C>G p.L1855V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100824196; called by muse, mutect2, varscan2
- TRAM2 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV51732336, COSV51735114; called by muse, mutect2, varscan2
- TRPV3 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100027530, COSV100028062; called by muse, mutect2, varscan2
- TSPAN14 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV99627910; called by muse, mutect2, varscan2
- TTN | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | PolyPhen benign (0.02); catalogued as rs754127089, COSV59954418; called by muse, mutect2, varscan2
- UBXN4 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV99739499; called by muse, mutect2, varscan2
- UMPS | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99229244; called by muse, mutect2, varscan2
- VCAM1 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658206, COSV99658821; called by muse, mutect2, varscan2
- VCP | c.1958G>T p.R653L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100734318; called by muse, mutect2
- VN1R4 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs566861600, COSV60805595; called by muse, mutect2, varscan2
- VSTM1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100618885; called by muse, mutect2, varscan2
- WDR91 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV60368703; called by muse, mutect2, varscan2
- ZAN | c.5712C>G p.F1904L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100770136; called by muse, mutect2, varscan2
- ZBTB11 | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.122); catalogued as rs779447195, COSV100465739; called by muse, mutect2, varscan2
- ZNF208 | c.1861G>T p.V621F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.222); catalogued as rs1279706360, COSV101237173, COSV68100893; called by muse, varscan2
- ZNF222 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99496529; called by muse, mutect2, varscan2
- ZNF232 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV100005782; called by muse, mutect2, varscan2
- ZNF292 | c.3565C>T p.P1189S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1490979416, COSV100370940; called by muse, mutect2, varscan2
- ZNF416 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99543910; called by muse, mutect2, varscan2
- ZNF44 | c.920C>T p.S307F (on ENST00000356109 / NM_001164276.2; = p.S259F on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1008969906, COSV100633656; called by muse, mutect2, varscan2
- ZNF451 | c.1900C>G p.H634D | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100675039; called by muse, mutect2, varscan2
- ZNF625 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100863528; called by muse, mutect2, varscan2
- ZNF678 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV59388472; called by muse, mutect2, varscan2
- ZNF700 | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99583733; called by muse, mutect2, varscan2
- ZNF77 | c.879G>C p.E293D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100094631, COSV58822117; called by muse, mutect2, varscan2
- ZRANB1 | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100456816; called by muse, mutect2
- IL6R | c.1343C>A p.P448Q | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); called by muse, mutect2
- PAX3 | c.1291C>A p.Q431K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- PRAMEF18 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SPANXB1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 27/631 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.943); called by muse, mutect2
- ZNF764 | c.73del p.A25Lfs*2 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- ANKFY1 | c.3192C>G p.V1064= (on ENST00000341657 / NM_001330063.2; = p.V1065= on NM_016376.5) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100493057; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1872G>T p.V624= | Silent (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- AP4S1 | c.198C>T p.F66= | Silent (SNP) | VAF 47/217 reads (22%) | catalogued as COSV99364368; called by muse, mutect2, varscan2
- AP5Z1 | c.2412C>T p.L804= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs779938191, COSV100804205; called by muse, varscan2
- APOA5 | c.24C>T p.L8= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99911447; called by muse, mutect2, varscan2
- APOBR | c.1011C>T p.A337= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1408328573, COSV100112817; called by muse, varscan2
- ARAP3 | c.360C>T p.L120= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs201975820; called by muse, mutect2, varscan2
- ATP6V0A4 | c.891C>T p.I297= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV59472679; called by muse, mutect2, varscan2
- BTNL8 | c.33C>A p.L11= | Silent (SNP) | VAF 109/324 reads (34%) | catalogued as COSV99180549; called by muse, mutect2, varscan2
- CARMIL3 | c.3147G>A p.K1049= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100549795; called by muse, mutect2, varscan2
- CCL26 | c.105C>T p.F35= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV99139162; called by muse, mutect2, varscan2
- CEP57L1 | c.423C>G p.L141= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs770707035, COSV100425937; called by muse, mutect2, varscan2
- CLCC1 | c.1551C>G p.L517= (on ENST00000356970 / NM_001377464.1; = p.L467= on NM_015127.5) | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV51444935; called by muse, mutect2, varscan2
- CLCN2 | c.1638G>A p.Q546= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV99658914; called by muse, mutect2, varscan2
- CLINT1 | c.1395C>T p.V465= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99753948; called by muse, mutect2, varscan2
- COL4A1 | c.1191A>C p.G397= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV101011446; called by muse, mutect2, varscan2
- CPPED1 | c.750G>A p.R250= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs753835597, COSV99903511; called by muse, mutect2, varscan2
- DDX51 | c.609T>C p.P203= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs756000486, COSV100223174; called by muse, mutect2, varscan2
- DEPTOR | c.339C>T p.L113= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as COSV99639161; called by muse, mutect2, varscan2
- DHX35 | c.1821G>C p.L607= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV52670096, COSV52671440; called by muse, mutect2, varscan2
- DLGAP4 | c.2685C>T p.I895= (on ENST00000339266 / NM_001365621.1; = p.I892= on NM_014902.6) | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as COSV100211532; called by muse, mutect2, varscan2
- DNAH9 | c.4962C>T p.L1654= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs753404936, COSV99306146, COSV99307464; called by muse, mutect2, varscan2
- DUSP8 | c.207C>T p.L69= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100524201; called by muse, mutect2, varscan2
- EYA2 | c.183G>A p.Q61= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as COSV100427197, COSV57949713; called by muse, mutect2, varscan2
- FBXO10 | c.2870G>A p.*957= | Silent (SNP) | VAF 57/173 reads (33%) | catalogued as COSV99447122; called by muse, mutect2, varscan2
- FGF13 | c.699G>C p.L233= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as COSV100263861, COSV100264526, COSV59543589; called by muse, mutect2, varscan2
- FMN2 | c.246G>A p.K82= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV60433211; called by muse, mutect2, varscan2
- FZD8 | c.1743C>G p.P581= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs370557580, COSV65967830; called by muse, mutect2, varscan2
- GLT8D2 | c.699C>T p.A233= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100674162, COSV62561120; called by muse, mutect2, varscan2
- GPC5 | c.1626T>A p.T542= | Silent (SNP) | VAF 78/175 reads (45%) | catalogued as COSV100995242; called by muse, mutect2, varscan2
- GPR17 | c.732C>T p.I244= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV99760722; called by muse, mutect2, varscan2
- HSPA9 | c.1233C>G p.V411= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99785635; called by muse, varscan2
- IL12A | c.717G>A p.R239= | Silent (SNP) | VAF 23/183 reads (13%) | catalogued as rs778010501, COSV99975850; called by muse, mutect2, varscan2
- KCNK5 | c.459G>C p.V153= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV100851912; called by muse, mutect2, varscan2
- KIR3DL3 | c.981G>A p.G327= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99400124; called by muse, mutect2, varscan2
- KRT76 | c.654C>T p.L218= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV100196439; called by muse, mutect2, varscan2
- LGI3 | c.180G>A p.R60= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100103177; called by muse, varscan2
- LRRC6 | c.924C>T p.F308= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1202535324, COSV51540137, COSV99138405; called by muse, mutect2, varscan2
- LTBP3 | c.2769C>T p.F923= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV99534490; called by muse, varscan2
- MAP2K1 | c.1119T>G p.G373= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV100199261; called by muse, mutect2, varscan2
- MCL1 | c.762C>T p.F254= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV100329682; called by muse, mutect2, varscan2
- MEP1A | c.1554G>C p.R518= | Silent (SNP) | VAF 50/231 reads (22%) | catalogued as COSV100043018; called by muse, mutect2, varscan2
- MTERF2 | c.99C>T p.F33= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV53528464, COSV99526955; called by muse, mutect2, varscan2
- MTMR3 | c.2250G>A p.L750= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60302797; called by muse, mutect2, varscan2
- MUC16 | c.19650G>A p.V6550= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV67479052; called by muse, mutect2, varscan2
- NAB1 | c.1155G>A p.E385= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100493123; called by muse, mutect2
- NCBP2L | c.72C>T p.F24= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100966511, COSV100966521; called by muse, mutect2, varscan2
- NCKIPSD | c.1476G>A p.Q492= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV99584163; called by muse, mutect2, varscan2
- NEXN | c.1083T>C p.Y361= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1060504549, COSV100331343; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXN | c.1212G>A p.E404= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100331344; called by muse, mutect2
- NID2 | c.1164G>A p.E388= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99357082; called by muse, mutect2, varscan2
- OLFML2A | c.879C>T p.Y293= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99992819; called by muse, mutect2, varscan2
- OR4N5 | c.201C>T p.A67= | Silent (SNP) | VAF 44/253 reads (17%) | catalogued as COSV100374192; called by muse, mutect2, varscan2
- OR7D2 | c.504C>T p.F168= | Silent (SNP) | VAF 69/173 reads (40%) | catalogued as COSV100713032, COSV60139687; called by muse, mutect2, varscan2
- P2RY4 | c.333C>A p.V111= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100997044; called by muse, mutect2
- PAQR4 | c.402C>T p.I134= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as rs777390479, COSV99234209; called by muse, mutect2, varscan2
- PUSL1 | c.687C>T p.F229= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs1240080534, COSV100028589; called by muse, mutect2, varscan2
- PYHIN1 | c.780G>A p.K260= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100932396; called by muse, mutect2, varscan2
- RALYL | c.828G>A p.E276= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV101569396; called by muse, mutect2, varscan2
- REG3G | c.483T>C p.Y161= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99709632; called by muse, mutect2, varscan2
- RNF133 | c.585G>A p.V195= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100411713; called by muse, mutect2, varscan2
- RTEL1 | c.2676G>A p.Q892= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1178761371, COSV100542728; called by muse, mutect2
- SBSPON | c.111C>T p.F37= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs768094773, COSV99817682; called by muse, mutect2
- SCYL1 | c.1167C>A p.I389= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99533616, COSV99534481; called by muse, varscan2
- SCYL1 | c.1227C>T p.V409= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99534485; called by muse, varscan2
- SLC43A1 | c.1593C>T p.F531= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs764153406, COSV99561166; called by muse, mutect2, varscan2
- SLC43A3 | c.1137C>T p.F379= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs767987515, COSV61450853; called by muse, varscan2
- SLC4A9 | c.1488C>T p.F496= (on ENST00000507527 / NM_001258428.2; = p.F472= on NM_031467.3) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99139629; called by muse, mutect2, varscan2
- SLC6A20 | c.384G>A p.L128= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV100653898; called by muse, mutect2, varscan2
- SLC8A2 | c.1404C>T p.D468= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs372168824; called by muse, mutect2, varscan2
- SLCO2A1 | c.834C>T p.F278= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs765647324, COSV100189239; called by muse, mutect2, varscan2
- SNX21 | c.171C>G p.L57= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100701799; called by muse, mutect2
- SYNJ2 | c.4032C>T p.F1344= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100840576, COSV62898664; called by muse, mutect2, varscan2
- TFPI | c.198C>T p.I66= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99259504; called by muse, mutect2, varscan2
- TLL2 | c.1233C>T p.V411= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV100780433; called by muse, mutect2, varscan2
- TP53I13 | c.201C>T p.F67= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99838366; called by muse, mutect2, varscan2
- TRPC1 | c.2178G>A p.K726= (on ENST00000476941 / NM_001251845.2; = p.K692= on NM_003304.4) | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99859218; called by muse, mutect2
- TRPC4 | c.2142G>T p.V714= (on ENST00000379705 / NM_016179.4; = p.V719= on NM_003306.3) | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as COSV100157633, COSV100157756; called by muse, mutect2, varscan2
- TRRAP | c.10344G>A p.L3448= (on ENST00000359863 / NM_001244580.1; = p.L3419= on NM_003496.3) | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100722802; called by muse, mutect2, varscan2
- USE1 | c.138G>C p.L46= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99812596; called by muse, mutect2
- YEATS2 | c.4008G>A p.Q1336= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100528195; called by muse, mutect2
- ZNF160 | c.90G>A p.R30= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100762449; called by muse, mutect2, varscan2
- ZNF211 | c.1236C>T p.L412= (on ENST00000347302 / NM_198855.4; = p.L425= on NM_006385.5) | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99560428; called by muse, mutect2, varscan2
- ZNF296 | c.90C>T p.L30= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV54319841; called by muse, mutect2, varscan2
- DUSP4 | c.433+4316G>A | Intron (SNP) | VAF 19/92 reads (21%) | catalogued as rs779053377, COSV99530009; called by muse, mutect2, varscan2
- RPL13A | c.342+83C>T | Intron (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99201341; called by muse, mutect2, varscan2
- SGK1 | chr6:134177747 G>T | 5'Flank (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99398978; called by muse, mutect2, varscan2
